Surgical pathology report (de-identified scan), TCGA case TCGA-V5-A7RB, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Duke University, specimen TCGA-V5-A7RB-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:
Esophageal cancer

GROSS EXAMINATION:
Outside case A:
Date of surgery:
Number of slides:

5

Received from:

Department of Pathology

Tel: [REDACTED]

Fax: [REDACTED]

Outside path report received? Yes
Material to be returned? Yes

MICROSCOPIC EXAMINATION:
Microscopic examination is performed.

DIAGNOSIS:

A. OUTSIDE CASE, [REDACTED]
DATE OF PROCEDURE [REDACTED]:

- A. "DISTAL ESOPHAGEAL MASS", BIOPSY:
INTRAMUCOSAL ADENOCARCINOMA, AT LEAST. SEE NOTE.
NO BARRETT'S ESOPHAGUS IS PRESENT IN THIS SAMPLE.
- B. "ASCENDING COLON POLYP" POLYPECTOMY:
SERRATE POLYP WITH FEATURES SUGGESTIVE OF A SESSILE SERRATED ADENOMA.
NEGATIVE FOR CONVENTIONAL DYSPLASIA.
- C. "TRANSVERSE COLON POLYP" POLYPECTOMY:
TUBULAR ADENOMA.
- D. "DESCENDING COLON POLYP" POLYPECTOMY:
TUBULAR ADENOMA.
- E. "RECTAL POLYP" POLYPECTOMY:
HYPERPLASTIC POLYP.

NOTE: The esophageal biopsy demonstrates squamous mucosa with undermining intramucosal adenocarcinoma (pT1a), moderately to poorly differentiated. Although highly suspicious, definitive submucosal invasion is not identified. Dr. [REDACTED] has reviewed this part and concurs with the diagnosis.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

Performed by:

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Esophagus, distal
third 215.5
JAS 11/16/14

[page 2 of 2]
Patient: [REDACTED]

Path Report: Final [REDACTED]

CLINICAL INFORMATION:

year old male patient with 1.5 cm perihepatic node and history of esophageal adenocarcinoma.

CLINICAL EXAMINATION:

Ultrasound guided FNA performed by gastroenterologist

MATERIAL SUBMITTED:

5 prestained smears, 4 prefixed smears, and fluid for sediment cell block.

MICROSCOPIC DESCRIPTION:

Microscopic examination is performed.

DIAGNOSTIC INTERPRETATION:

Source: Lymph node, perihepatic, ultrasound guided fine needle aspiration biopsy (smears, cell block).

Immediate assessment: Suspicious

Final diagnosis: DIAGNOSTIC OF MALIGNANCY.

Malignant cells are present in a background of lymph node tissue, consistent with a metastatic adenocarcinoma.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

Performed by: [REDACTED]

Attending MD:

Ordering MD:

MDA Discrepancy		✓

Source: NCI Genomic Data Commons file 5cc0b897-c8c6-4562-8e5a-82c01621b31d (TCGA-V5-A7RB.3F84FEC7-0389-4AF8-AAC1-F957B6282D67.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).